Somatic mutation profile of tumor specimen TCGA-44-2662-01B (aliquot TCGA-44-2662-01B-02D-A271-08) from TCGA case TCGA-44-2662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.7 years (24,014 days).
Specimen TCGA-44-2662-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 789062bc-54e7-413f-84b2-29e5c58c9adf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2662-10A (Blood Derived Normal), aliquot TCGA-44-2662-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6393acee-06cd-479b-98aa-fd1e7e6bf5f5

The open-access MAF lists 193 somatic variants for this specimen: 140 protein-altering or splice-affecting, 51 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 51, Nonsense Mutation 9, Splice Site 4, Frame Shift Del 3, RNA 2, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1862A>G p.N621S (on ENST00000288602 / NM_001374244.1; = p.N581S on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs121913370, COSV56058108, COSV56106422, COSV56110832; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.882C>T p.L294= | Splice Region (SNP) | VAF 16/108 reads (15%) | catalogued as rs63751707, CS086119, COSV51615064; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- ABCA12 | c.340A>T p.N114Y | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV55951076; called by muse, mutect2, varscan2
- ABCA13 | c.9493G>C p.D3165H | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV71284199; called by muse, mutect2
- ABCA13 | c.14104G>A p.E4702K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV68944021; called by muse, mutect2
- ACTN2 | c.1347C>G p.S449R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100857132, COSV63972620; called by muse, mutect2, varscan2
- ALG3 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546890576, COSV56610384; called by muse, mutect2, varscan2
- AMN | c.163-1G>A p.X55_splice | Splice Site (SNP) | VAF 34/151 reads (23%) | catalogued as COSV54486203; called by muse, mutect2, varscan2
- ANAPC1 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV61974574; called by muse, mutect2
- AP4B1 | c.1775C>A p.S592* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as COSV56723643, COSV56724960; called by muse, mutect2, varscan2
- ATP11C | c.2737A>T p.M913L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59560166; called by muse, mutect2, varscan2
- BAX | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV53169282; called by muse, mutect2, varscan2
- BCAS3 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as rs771698366, COSV66770605; called by muse, mutect2, varscan2
- BCHE | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52254138; called by muse, mutect2, varscan2
- BMERB1 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV55506397; called by muse, mutect2, varscan2
- C1orf87 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV64596255; called by muse, mutect2, varscan2
- C2orf78 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.127); catalogued as rs1409069598, COSV68516575; called by muse, mutect2, varscan2
- CACNA1E | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV62384201; called by muse, mutect2, varscan2
- CCDC146 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53544797; called by muse, mutect2, varscan2
- CCDC88A | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55057407; called by muse, mutect2, varscan2
- CCDC90B | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52623501; called by muse, mutect2, varscan2
- CCP110 | c.2065G>C p.E689Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV66816618; called by muse, mutect2, varscan2
- CEP350 | c.5746G>A p.D1916N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1290923833, COSV62599414, COSV62610166; called by muse, mutect2, varscan2
- CETN3 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV51616945; called by muse, mutect2, varscan2
- CHAMP1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 66/358 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs1555379780, COSV63521883; called by muse, mutect2, varscan2
- CHRNA4 | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64718614; called by muse, mutect2, varscan2
- CNTLN | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52068519; called by mutect2, varscan2
- CNTN5 | c.1646A>G p.Y549C | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54286974; called by muse, mutect2
- COBL | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV54339839; called by muse, mutect2, varscan2
- CYFIP2 | c.2231G>T p.S744I (on ENST00000616178 / NM_001291722.2; = p.S719I on NM_014376.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59029806; called by muse, mutect2, varscan2
- DHRS9 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748041645, COSV59139004; called by muse, mutect2, varscan2
- DKK2 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV53394673; called by muse, mutect2
- DNAH10 | c.4962C>G p.I1654M (on ENST00000409039; = p.I1593M on NM_207437.3) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV68989065, COSV68995673; called by muse, mutect2, varscan2
- DNAJC14 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV54477846; called by muse, mutect2, varscan2
- DPY19L4 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs1385399777, COSV68962348; called by muse, mutect2
- ERI3 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV64830371; called by muse, mutect2
- EXOG | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55062785; called by muse, mutect2, varscan2
- FLCN | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 37/201 reads (18%) | catalogued as COSV53257576; called by muse, mutect2, varscan2
- FMN2 | c.4759T>G p.L1587V | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100144541, COSV60419697; called by muse, mutect2
- FRMD8 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs759320847, COSV53683382; called by muse, mutect2, varscan2
- FSIP2 | c.16905G>C p.K5635N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100554337; called by muse, mutect2, varscan2
- GOLGA4 | c.6639G>T p.L2213F | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100728697; called by muse, mutect2, varscan2
- GOLGA4 | c.6640G>T p.E2214* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as COSV100728700; called by muse, mutect2, varscan2
- GPATCH1 | c.1389G>T p.R463S | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV50111020, COSV50111767, COSV50112587; called by muse, mutect2
- GSDMC | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs910419404, COSV52692967; called by muse, mutect2, varscan2
- GSDMD | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV52796493; called by muse, mutect2
- GSDME | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV61651075; called by muse, mutect2, varscan2
- GTF2F1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.925); catalogued as rs1416347587, COSV66725005; called by muse, mutect2
- GTF2I | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs145729076; called by muse, mutect2
- GUCY1A2 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); catalogued as COSV56479596; called by muse, mutect2
- HCN1 | c.1708A>T p.N570Y | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV57496403; called by muse, mutect2
- IL1RAPL1 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56234164, COSV56241733; called by muse, mutect2, varscan2
- IMPG2 | c.3247G>A p.E1083K | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV51974431; called by muse, mutect2
- IWS1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 8/125 reads (6%) | catalogued as COSV54866847; called by muse, mutect2
- JAKMIP2 | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV54598719; called by muse, mutect2, varscan2
- KIF15 | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); catalogued as COSV100392470, COSV58158904; called by muse, mutect2, varscan2
- KIF26B | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs375797576; called by muse, mutect2
- KIN | c.479A>T p.K160M | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65430057; called by muse, mutect2
- KLHL15 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60139363; called by muse, mutect2, varscan2
- KLHL3 | c.1578C>A p.C526* | Nonsense Mutation (SNP) | VAF 33/187 reads (18%) | catalogued as COSV59051273, COSV59054767; called by muse, mutect2, varscan2
- KNDC1 | c.4697C>G p.S1566C | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757639617, COSV58832188, COSV58841310; called by muse, mutect2, varscan2
- KRTAP23-1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV61935551; called by muse, mutect2
- LGALS9 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56348151; called by muse, mutect2, varscan2
- LGR4 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.985); catalogued as COSV60820240; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.641C>A p.A214D | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.266); catalogued as COSV53275994, COSV53278487; called by muse, mutect2, varscan2
- MACF1 | c.5555C>T p.S1852L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as COSV57109524; called by muse, mutect2, varscan2
- MANBA | c.1400T>A p.L467H (on ENST00000642252; = p.L421H on NM_005908.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56963278; called by muse, mutect2, varscan2
- MAP3K13 | c.1170-1G>A p.X390_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as COSV53984357; called by muse, mutect2, varscan2
- MMRN1 | c.2906C>A p.P969Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV53338104, COSV99306646; called by muse, mutect2, varscan2
- MTBP | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59961276, COSV59961624; called by muse, mutect2, varscan2
- MUC16 | c.18502G>C p.G6168R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as COSV67449722, COSV67478144; called by muse, mutect2, varscan2
- MYCBP2 | c.4337G>C p.G1446A (on ENST00000357337; = p.G1484A on NM_015057.5) | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV62011668; called by muse, mutect2, varscan2
- MYLK2 | c.1409T>C p.V470A | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65658665; called by muse, mutect2, varscan2
- N4BP1 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV52209788; called by muse, mutect2
- NCKAP1L | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV53204058; called by muse, mutect2
- NIPAL4 | c.1206C>G p.F402L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV57423918, COSV57430406; called by muse, mutect2, varscan2
- NLRP13 | c.1348C>G p.Q450E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV100738131, COSV61620365; called by muse, mutect2
- NPPA | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.049); catalogued as COSV56738360; called by muse, mutect2
- NUMB | c.981C>G p.I327M (on ENST00000355058; = p.I316M on NM_003744.5) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61828178, COSV61830428; called by muse, mutect2, varscan2
- OR10X1 | c.124T>A p.F42I | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as COSV63767025; called by muse, mutect2, varscan2
- OR2L8 | c.513G>T p.R171S | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61725780, COSV61728604; called by muse, mutect2, varscan2
- OR2M4 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV60707445; called by muse, mutect2
- OR7A5 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV59234224; called by muse, varscan2
- PCDHA8 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs146582216, COSV65323904; called by muse, mutect2
- PDGFRB | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55801742; called by muse, mutect2
- PHKB | c.2737G>C p.D913H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as COSV54515846; called by muse, mutect2, varscan2
- PIGX | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56359154; called by muse, mutect2
- PLD5 | c.1202C>A p.A401E (on ENST00000442594; = p.A339E on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV59135609; called by muse, mutect2, varscan2
- PPP2R2A | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV60095931; called by muse, mutect2
- PPP6R3 | c.2493A>C p.K831N (on ENST00000393800 / NM_001352375.2; = p.K751N on NM_018312.5) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV55722277; called by muse, mutect2, varscan2
- PREPL | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.938); catalogued as COSV53215383; called by muse, mutect2, varscan2
- PTPRZ1 | c.5657C>G p.P1886R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV66431672; called by muse, mutect2, varscan2
- RIF1 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV54613278; called by muse, mutect2, varscan2
- RPL11 | c.296C>T p.S99L (on ENST00000374550 / NM_001199802.1; = p.S100L on NM_000975.5) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs11556036, COSV65778420; called by muse, mutect2, varscan2
- RTEL1 | c.2033C>G p.S678C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV58891288, COSV58901671; called by muse, mutect2, varscan2
- RUFY1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60158676; called by muse, mutect2
- RYR1 | c.11362G>C p.E3788Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV62090965, COSV62091055; called by muse, mutect2
- SAMD15 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV53625454; called by muse, mutect2, varscan2
- SLC12A7 | c.343-2A>T p.X115_splice | Splice Site (SNP) | VAF 16/155 reads (10%) | catalogued as COSV53754988; called by muse, mutect2, varscan2
- SLC26A3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs868438571, COSV60639061, COSV60640869; called by muse, mutect2
- SLC39A12 | c.1793C>G p.S598C (on ENST00000377369 / NM_001145195.2; = p.S561C on NM_152725.3) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs765088632, COSV66195699; called by muse, mutect2
- SLCO5A1 | c.1537G>T p.V513L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV52654919; called by muse, mutect2, varscan2
- SMAD4 | c.431C>G p.S144* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV61685296, COSV61696805; called by muse, mutect2, varscan2
- SMG5 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV62434193, COSV62434555; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.917G>C p.*306Sext*1 | Nonstop Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as rs1259641661, COSV60322588; called by muse, mutect2, varscan2
- STAG3 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV57928012; called by muse, mutect2, varscan2
- TACC2 | c.6073G>C p.D2025H (on ENST00000334433; = p.D103H on NM_006997.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53277076, COSV53278918; called by muse, mutect2, varscan2
- TBC1D31 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs144947635; called by muse, mutect2
- THAP12 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.025); catalogued as COSV52609641, COSV52611941; called by muse, mutect2, varscan2
- TLK2 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); catalogued as rs777808122, COSV58297734; called by muse, mutect2, varscan2
- TMEM108 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); catalogued as COSV58865488; called by muse, mutect2, varscan2
- TRA2A | c.35G>C p.R12T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51715959; called by muse, mutect2, varscan2
- TRBC2 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs782153350; called by muse, mutect2, varscan2
- TRHDE | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53835267; called by muse, mutect2, varscan2
- TRIM7 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51240776; called by muse, mutect2, varscan2
- TRPM7 | c.3053G>T p.R1018I | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57914027; called by muse, mutect2, varscan2
- TSC22D2 | c.1610A>T p.Q537L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV62622252; called by muse, mutect2, varscan2
- TSHZ3 | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.378); catalogued as COSV53665760; called by muse, mutect2, varscan2
- TTC23 | c.994-1G>A p.X332_splice | Splice Site (SNP) | VAF 10/71 reads (14%) | catalogued as COSV50440833; called by muse, mutect2, varscan2
- TTC8 | c.1374G>A p.M458I (on ENST00000338104 / NM_001288781.1; = p.M442I on NM_144596.4) | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as rs758330370, COSV57626554; called by muse, varscan2
- TTN | c.11507A>T p.Q3836L (on ENST00000591111; = p.Q3790L on NM_003319.4) | Missense Mutation (SNP) | VAF 24/137 reads (18%) | catalogued as COSV59914943; called by muse, mutect2, varscan2
- TYRO3 | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55481275, COSV55487658; called by muse, mutect2, varscan2
- UBAP2 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.366); catalogued as COSV62545428, COSV62548950; called by muse, mutect2
- UNC5B | c.2063C>G p.S688C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV58974964; called by muse, mutect2, varscan2
- UQCRQ | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51525893; called by muse, mutect2, varscan2
- USP34 | c.3709C>G p.L1237V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV68398939; called by muse, mutect2
- UVRAG | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV62101812; called by muse, mutect2
- ZBBX | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV56784066; called by muse, mutect2, varscan2
- ZFHX4 | c.1163C>G p.T388S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV50551279; called by muse, mutect2, varscan2
- ZFP36L2 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.373); catalogued as COSV56698979, COSV56699574, COSV99143900; called by muse, mutect2
- ZNF507 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758381137, COSV61330269; called by muse, mutect2
- ZNF546 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV61257303; called by muse, mutect2, varscan2
- ZNF777 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56096276; called by muse, mutect2
- AHNAK | c.345_357del p.S115Rfs*15 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- ANKRD24 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MFSD8 | c.1271del p.V424Gfs*2 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- PLEKHG1 | c.1700_1704del p.S567Ffs*10 | Frame Shift Del (DEL) | VAF 23/135 reads (17%) | called by mutect2, pindel, varscan2
- PTPN20 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- SPAST | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2
- ABHD11 | c.846C>T p.L282= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV56105325; called by muse, mutect2, varscan2
- ADD3 | c.639C>T p.F213= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV53320887; called by muse, mutect2, varscan2
- AKT2 | c.627C>T p.H209= | Silent (SNP) | VAF 23/741 reads (3%) | catalogued as COSV60907765; called by muse, mutect2
- ATN1 | c.930C>G p.L310= | Silent (SNP) | VAF 8/127 reads (6%) | catalogued as COSV63110355; called by muse, mutect2
- BCAR1 | c.2238C>T p.F746= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV50779076; called by muse, mutect2, varscan2
- CACNA1B | c.1572C>G p.L524= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV53116322; called by muse, mutect2, varscan2
- CACNA1F | c.723A>T p.A241= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV59903314; called by muse, mutect2, varscan2
- CACNG4 | c.981G>T p.V327= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV50924266; called by muse, mutect2, varscan2
- CCDC87 | c.2034G>A p.L678= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV59578490; called by muse, mutect2, varscan2
- CD59 | c.24C>G p.V8= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV60918993; called by muse, mutect2, varscan2
- CPA3 | c.441T>C p.S147= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV56043997; called by muse, mutect2, varscan2
- CSMD1 | c.7977T>C p.H2659= (on ENST00000520002; = p.H2658= on NM_033225.6) | Silent (SNP) | VAF 26/281 reads (9%) | catalogued as rs1420433528, COSV59289766; called by muse, mutect2
- DDN | c.1545G>C p.S515= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- DSTN | c.108C>T p.V36= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV55712305; called by muse, mutect2, varscan2
- EVI5 | c.1203C>T p.V401= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV64825788; called by muse, mutect2, varscan2
- FBXO41 | c.2490G>A p.G830= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as rs1185112178, COSV54582328; called by muse, mutect2
- FXR1 | c.834C>T p.F278= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as COSV59761409; called by muse, mutect2, varscan2
- GARS1 | c.1371G>A p.E457= | Silent (SNP) | VAF 30/222 reads (14%) | catalogued as COSV66827960; called by muse, mutect2, varscan2
- GC | c.138C>A p.V46= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV56735678, COSV99909497; called by muse, mutect2
- GPR183 | c.969G>C p.L323= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as COSV63117180; called by muse, mutect2, varscan2
- GRK6 | c.1458C>T p.V486= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV62681920; called by muse, mutect2, varscan2
- HYI | c.765C>T p.F255= (on ENST00000372434 / NM_001330526.2; = p.F230= on NM_031207.6) | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV65094217; called by muse, mutect2, varscan2
- IGSF22 | c.1680G>A p.Q560= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV60031515; called by muse, mutect2
- LNPEP | c.2277G>A p.E759= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV51476664; called by muse, mutect2, varscan2
- LRP1 | c.3468C>T p.T1156= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1347019663, COSV54503612; called by muse, mutect2, varscan2
- MAST3 | c.2781G>T p.S927= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV53218022; called by muse, mutect2, varscan2
- MED12 | c.4134C>G p.L1378= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV61333791; called by muse, mutect2, varscan2
- MED12 | c.4293C>A p.L1431= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV61333804; called by muse, mutect2, varscan2
- MOCS3 | c.600C>T p.L200= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV54865742; called by muse, mutect2, varscan2
- MYCBP2 | c.4287G>C p.L1429= (on ENST00000357337; = p.L1467= on NM_015057.5) | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs377177103, COSV62011678; called by muse, mutect2, varscan2
- OR1C1 | c.867C>A p.I289= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV68715457; called by muse, mutect2, varscan2
- PCLO | c.2988G>A p.V996= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV61619415; called by muse, mutect2, varscan2
- PCMTD2 | c.564C>T p.V188= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV55059281; called by muse, mutect2, varscan2
- PDPR | c.2310C>T p.F770= | Silent (SNP) | VAF 26/194 reads (13%) | catalogued as COSV55349631; called by muse, mutect2, varscan2
- PHOX2B | c.471G>A p.E157= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV99890932; called by muse, mutect2
- PKHD1 | c.5166C>T p.I1722= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV61863471; called by muse, mutect2
- PNPLA7 | c.150C>T p.F50= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1052637819, COSV52995085; called by muse, mutect2, varscan2
- POLK | c.1197C>T p.S399= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as COSV54032674; called by muse, mutect2
- POT1 | c.375C>T p.F125= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV62928375; called by muse, mutect2, varscan2
- PSD3 | c.2758C>T p.L920= (on ENST00000440756; = p.L919= on NM_015310.4) | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as rs377209838, COSV54067396; called by muse, mutect2, varscan2
- PTBP3 | c.567C>G p.L189= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV52956154; called by muse, mutect2, varscan2
- SLC35B2 | c.1221C>G p.L407= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as COSV51487931; called by muse, mutect2
- SLC38A11 | c.951C>A p.L317= (on ENST00000409149 / NM_001351539.1; = p.L295= on NM_173512.2) | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV58052069; called by muse, mutect2
- SZT2 | c.3717C>T p.V1239= (on ENST00000634258 / NM_001365999.1; = p.V1182= on NM_015284.4) | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV65167756; called by muse, mutect2, varscan2
- TENM1 | c.708C>A p.T236= | Silent (SNP) | VAF 17/119 reads (14%) | catalogued as COSV64426331; called by muse, mutect2, varscan2
- TEX264 | c.360C>T p.F120= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV58133614; called by muse, mutect2, varscan2
- TRRAP | c.723G>A p.L241= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV62840348, COSV62848788; called by muse, mutect2, varscan2
- ULBP3 | c.684C>G p.L228= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV66253992; called by muse, mutect2
- UTRN | c.8820C>G p.L2940= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV62307722; called by muse, mutect2, varscan2
- ZFHX3 | c.10881G>A p.A3627= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs892312481, COSV51710753; called by muse, mutect2, varscan2
- ZFPM2 | c.969G>A p.V323= | Silent (SNP) | VAF 33/158 reads (21%) | catalogued as COSV65872748; called by muse, mutect2, varscan2
- OR2W5 | n.1042C>A | RNA (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- SNORD115-3 | n.1G>A | RNA (SNP) | VAF 62/361 reads (17%) | catalogued as rs761103960; called by muse, mutect2, varscan2
